Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GI, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GI-06A (Metastatic).

[page 1 of 3]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

A) LEFT CERVICAL LYMPH NODES, LEVELS 2-5, NECK DISSECTION:

MELANOMA METASTATIC TO DERMIS

LARGEST TUMOR NODULE MEASURES 12MM IN GREATEST DIMENSION (LEVEL III SKIN ELIPSE), METASTATIC MELANOMA MEASURES 1.5 MM TO CLOSEST TISSUE EDGE.

TWO SEPARATE FOCI OF METASTATIC MELANOMA PRESENT IN SOFT TISSUE (SEE COMMENT)

MELANOMA, METASTATIC TO AT LEAST ONE OF THIRTY-FIVE LYMPH NODES (1/35).

Largest tumor deposit size: 1.5 x 1.0 mm.

Location: level III-IV

Extracapsular extension: absent

Actinic keratosis, tissue edges appear free

Submandibular gland, negative for tumor.

B) ADDITIONAL LEVEL 2 LYMPH NODES LEFT CERVICAL, NECK DISSECTION:

Five lymph nodes, negative for metastatic melanoma (0/5).

COMMENT

Some foci of metastatic melanoma in part A may represent additional positive lymph nodes, completely replaced by tumor (8mm x 4mm and 7mm x 4mm respectively, levels III and IV).

ICD-O-3

Melanoma NOS 8720/3

Site: Cervical lymph node c77.0

2011/27/13

PATHOLOGIC STAGE BASED ON PATHOLOGY MATERIAL REVIEWED IN THIS ACCESSION

Primary tumor: PT2

Regional lymph nodes: pN3

Distant metastases: pMx

(American Joint Committee on Cancer, 7th Edition, 2010)

For a complete description of prognostic factors please see prior provided in this report is a compilation of both this current specimen and that prior case.

The pTNM information

GROSS DESCRIPTION

(A) LEFT CERVICAL LYMPH NODES, LEVELS 2-5, STERILE FOR MELANOMA TISSUE BANK - A single left cervical dissection specimen (13.5 x 5.6 x 3.4 cm) that has two tan skin ellipses present. The level II tan skin ellipse (5.8 cm long and 1.0 cm in diameter) has a central tan-gray scar (2.2 cm in length and 0.2 cm in diameter). The level III skin ellipse (5.3 cm in length and 1.8 cm in diameter) has a central, somewhat circumscribed dark brown to black mass (1.1 x 1.0 x 0.9 cm) that is located 0.2 cm from the closest peripheral skin resection margin which is inked. There is also a salivary gland present in level II (4.1 x 2.9 x 1.3 cm) that is grossly intact with no gross tumor infiltrates. There are multiple tan-pink to black lymph nodes that range from 0.2 cm up to 1.3 cm.

Sterile material is submitted to the melanoma tissue bank.

INK CODE: Yellow - level II #1 skin ellipse peripheral resection margin; blue - level III, #2 skin ellipse peripheral resection margin.

SECTION CODE: A1, A2, level II skin ellipse; A3, A4, salivary gland; A5, A6, five possible intact level II lymph nodes, each cassette; A7, A8, one possible bisected lymph node, level II, each cassette; A9, A10, level III skin ellipse with mass; A11, six possible intact lymph nodes, levels III and IV; A12-A15, five possible intact lymph nodes, levels III and IV, each cassette; A16, two possible intact lymph nodes, level III-IV; A17, A18, one possible bisected lymph node, level III-IV, each cassette; A19, five possible intact lymph nodes, level V; A20, A21, one possible bisected lymph node, each cassette, level V.

(B) ADDITIONAL LEVEL 2 LYMPH NODES LEFT CERVICAL - A 2 x 2 x 0.3 cm tan-pink irregular piece of fibrous adipose tissue.

The cut surface reveals three possible lymph nodes ranging from 0.2 to 0.4 cm. The specimen is entirely submitted as follows.

SECTION CODE: B1, three possible lymph nodes; B2, remainder of the specimen.

BIOMARKER TESTING

[page 2 of 3]
Metastatic
Tumor Block: A9, Normal Block: A8

CLINICAL HISTORY
Melanoma.

SNOMED CODES
T-02300, M-87206, T-C4200
some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 3 of 3]
ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

Addendum completed by

COMMENT

Immunohistochemical studies were performed with antibodies for BRAF-V600E on block A9. The tumor cells are negative for BRAF-V600E. Correlation with molecular studies is necessary.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria *hw 10/28/13* *No Hx*

	Yes	No
HIPAA Discrepancy	(1) Report text still	☒
Prior Malignancy History	(2) Sequences all still	☒

Source: NCI Genomic Data Commons file 0aa7e448-8f2a-4100-ac55-7f7938b05acd (TCGA-D3-A8GI.15C6CB85-4DCD-4233-82A5-2A408AD8E310.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).